Gene-level copy-number profile of tumor specimen ALCH-B3CY-TTP1-A from ALCHEMIST case ALCH-B3CY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,891 days).
Specimen ALCH-B3CY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d4089292-cac2-4c0d-9b30-746216b6ede7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3CY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,257 have no estimate.
https://portal.gdc.cancer.gov/files/38f1f89b-da8f-4a43-8ca3-8e337b26c985

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 11,518; copy number 2: 42,477; copy number 3: 4,190; copy number 4: 78; copy number 5: 13; copy number 6: 72; copy number 8: 4; copy number 11: 1; copy number 20: 2; copy number 30: 1; copy number 59: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:222,510,169–222,519,732, 1 gene: AL592148.2.
- chr5:179,455,415–179,456,095, 1 gene: AC136628.1.
- chr15:25,197,576–25,201,404, 3 genes (within-gene range 0–1): SNORD115-15, SNORD115-16, SNORD115-17.
- chr15:25,230,838–25,230,919, 1 gene (within-gene range 0–1): SNORD115-33.
- chr15:25,243,614–25,245,559, 2 genes (within-gene range 0–1): SNORD115-40, SNORD115-41.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 95 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,811,720–7,829,053, 3 genes, copy number 5: DEFB107A, DEFB105A, DEFB106A.
- chr9:137,434,364–137,459,334, 3 genes, copy number 6 (within-gene range 2–6): ENTPD8, NSMF, MIR7114.
- chr15:84,199,311–84,245,368, 3 genes, copy number 5–8: GOLGA2P7, RN7SL331P, GOLGA6L4.
- chr15:84,412,773–84,502,381, 5 genes, copy number 6: UBE2Q2P11, AC243562.3, Metazoa_SRP, UBE2Q2P12, AC048382.4.
- chr15:84,655,129–84,658,563, 1 gene, copy number 5: NMB.
- chr16:33,802,764–33,803,217, 1 gene, copy number 11: IGHV3OR16-12.
- chr18:21,704,957–24,402,714, 64 genes, copy number 5–6 (broad region; genes not listed).
- chr21:43,107,942–43,168,646, 1 gene, copy number 59 (within-gene range 2–59): AP001631.2.
- chr21:43,140,523–43,162,277, 2 genes, copy number 6–59: FRGCA, AP001631.1.
- chr21:44,107,373–44,131,181, 1 gene, copy number 5: PWP2.
- chr21:44,158,740–44,194,338, 3 genes, copy number 6–30: LINC01678, AP001056.2, AP001056.1.
- chr21:44,217,014–44,262,216, 5 genes, copy number 5–8: ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.
- chr22:21,114,607–21,128,063, 2 genes, copy number 20 (within-gene range 1–20): AP000550.1, POM121L7P.
- chr22:50,263,713–50,270,767, 1 gene, copy number 5: MAPK11.

Autosomal genes at a single copy (total copy number 1): 11,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
